Somatic mutation profile of tumor specimen TCGA-77-7335-01A (aliquot TCGA-77-7335-01A-11D-2042-08) from TCGA case TCGA-77-7335, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 62.6 years (22,863 days).
Specimen TCGA-77-7335-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c27570d-ff2c-4cc9-8a31-be98dcc7e632.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-7335-11A (Solid Tissue Normal), aliquot TCGA-77-7335-11A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3a69387-a53f-47a1-9112-ed442295b64a

The open-access MAF lists 243 somatic variants for this specimen: 175 protein-altering or splice-affecting, 60 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 60, Nonsense Mutation 11, Splice Site 6, Frame Shift Del 5, Intron 5, RNA 2, Splice Region 2, In Frame Ins 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as rs769387998, COSV55959969; called by muse, mutect2, varscan2
- ABCC1 | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs45517537, COSV60681773; called by muse, mutect2, varscan2
- ABHD16A | c.847A>T p.I283F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV101013166; called by muse, mutect2, varscan2
- ADGRF5 | c.3400C>T p.L1134F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345304; called by muse, mutect2, varscan2
- ALDH3B2 | c.319+1G>T p.X107_splice | Splice Site (SNP) | VAF 20/98 reads (20%) | catalogued as rs922832355, COSV100824015; called by muse, mutect2, varscan2
- ANKRD7 | c.613T>C p.C205R | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1448624412, COSV99501034; called by muse, mutect2, varscan2
- APLP1 | c.1777G>A p.G593R (on ENST00000221891 / NM_001024807.3; = p.G592R on NM_005166.4) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs1296100771, COSV55707169; called by muse, mutect2, varscan2
- ARHGAP5 | c.3163G>T p.D1055Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV100565172; called by muse, mutect2, varscan2
- ARSF | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100839554, COSV63839052; called by muse, mutect2, varscan2
- ASB5 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs188036445, COSV99641506; called by muse, mutect2, varscan2
- ASMT | c.952C>T p.H318Y (on ENST00000381229; = p.H346Y on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.46); catalogued as CM127754, COSV101172433; called by muse, mutect2, varscan2
- ATP8A2 | c.569T>A p.L190Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV99681223; called by muse, mutect2, varscan2
- BCAN | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100228014; called by muse, mutect2
- BIN3 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs776519160, COSV99373940; called by muse, mutect2, varscan2
- BOP1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1167544992; called by muse, mutect2, varscan2
- BRDT | c.753G>C p.K251N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100746272, COSV62864172, COSV62864212; called by muse, mutect2, varscan2
- BRINP3 | c.1746G>T p.E582D | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as COSV100818620, COSV66519075; called by muse, mutect2, varscan2
- BSND | c.395T>A p.L132Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100987617; called by muse, mutect2, varscan2
- C22orf15 | c.274C>A p.R92S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV100533605; called by muse, mutect2, varscan2
- C3orf20 | c.2069C>G p.P690R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99513697; called by muse, mutect2, varscan2
- CACNA1H | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs369566757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC73 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100067082; called by muse, mutect2, varscan2
- CD47 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100790108; called by muse, mutect2, varscan2
- CD72 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV99427371; called by muse, mutect2, varscan2
- CDH18 | c.1529G>C p.S510T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV56918965; called by muse, mutect2, varscan2
- CDX4 | c.455G>T p.S152I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100999113, COSV100999124; called by muse, mutect2, varscan2
- CEP164 | c.3626C>T p.T1209I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1175060061, COSV99633023; called by muse, mutect2, varscan2
- CHN2 | c.1129+1G>A p.X377_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99764863; called by muse, mutect2, varscan2
- CIITA | c.1543T>A p.C515S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100161710; called by muse, mutect2, varscan2
- CLDN6 | c.241C>A p.R81S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100172117; called by muse, mutect2, varscan2
- CSRNP3 | c.911C>A p.P304H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV58787743; called by muse, mutect2, varscan2
- DCC | c.1326C>A p.S442R | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100499143, COSV100499336; called by muse, mutect2, varscan2
- DCTN4 | c.1057A>G p.N353D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV101437541; called by muse, mutect2, varscan2
- DDX1 | c.2066C>T p.T689I | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99246125; called by muse, mutect2, varscan2
- DENND2B | c.81-1G>A p.X27_splice | Splice Site (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100567356; called by muse, mutect2, varscan2
- DLL1 | c.2100A>C p.K700N | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100816001; called by muse, mutect2, varscan2
- DMD | c.4519-1G>C p.X1507_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as CS013450, COSV63763531; called by muse, mutect2
- DNAJC5B | c.376T>G p.C126G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV99395537; called by muse, mutect2, varscan2
- DOCK6 | c.3711G>A p.T1237= | Splice Region (SNP) | VAF 6/21 reads (29%) | catalogued as rs139902327, COSV53910785, COSV53920639; called by muse, mutect2, varscan2
- EMSY | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369162436; called by muse, mutect2, varscan2
- ERICH3 | c.2281C>A p.Q761K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs1170742563, COSV58614932; called by muse, mutect2, varscan2
- ERICH3 | c.1569G>A p.M523I | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as COSV58601188; called by muse, mutect2, varscan2
- ERP44 | c.805A>G p.M269V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99316311; called by muse, mutect2, varscan2
- EVA1C | c.613G>C p.A205P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.46); catalogued as COSV100291274; called by muse, mutect2, varscan2
- FAT4 | c.3554G>C p.G1185A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101272223; called by muse, mutect2, varscan2
- FER1L6 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1005501042, COSV101205719; called by muse, mutect2, varscan2
- FGG | c.832G>C p.D278H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271801, COSV60196627; called by muse, mutect2
- FOSL1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778680030, COSV100440859; called by muse, mutect2, varscan2
- GALK2 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376875144, COSV59104143; called by muse, mutect2, varscan2
- GLT1D1 | c.749T>A p.V250D (on ENST00000442111 / NM_001366889.1; = p.V170D on NM_144669.3) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV99896375; called by muse, mutect2, varscan2
- GNA13 | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101457438; called by muse, mutect2, varscan2
- GNPAT | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1049596566, COSV100791602; called by muse, mutect2, varscan2
- GPC2 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 65/346 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99444504; called by muse, mutect2, varscan2
- GRK6 | c.823A>G p.I275V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs371992461; called by mutect2, varscan2
- H4C4 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs767500097, COSV100534397; called by muse, mutect2, varscan2
- HCLS1 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100100529; called by muse, mutect2, varscan2
- HDX | c.2020A>C p.T674P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99947040; called by muse, mutect2, varscan2
- HYDIN | c.6295G>T p.V2099L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99992490; called by muse, mutect2, varscan2
- ICA1 | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99655136; called by muse, mutect2, varscan2
- IGKV2D-28 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs770296882; called by mutect2, varscan2
- IGLV2-11 | c.131C>G p.T44S | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.079); catalogued as rs755736155; called by muse, mutect2, varscan2
- IGLV2-11 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); catalogued as rs747047277; called by muse, mutect2, varscan2
- IRX2 | c.1375G>C p.G459R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.069); catalogued as COSV100121668; called by muse, mutect2, varscan2
- ITGA3 | c.2924C>G p.S975C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV99143499; called by muse, mutect2, varscan2
- ITGA8 | c.868A>T p.R290* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100959099; called by muse, mutect2, varscan2
- KCNH7 | c.2656G>T p.D886Y | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100147413; called by muse, mutect2, varscan2
- KCNN3 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.535); catalogued as COSV99678061; called by muse, mutect2, varscan2
- KLRC2 | c.434G>T p.C145F | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101122668; called by muse, mutect2, varscan2
- KMT2C | c.6446C>G p.S2149* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as COSV100070210; called by muse, mutect2, varscan2
- KNL1 | c.2341T>A p.C781S (on ENST00000346991 / NM_170589.5; = p.C755S on NM_144508.5) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.324); catalogued as COSV100706249, COSV61154199; called by muse, mutect2, varscan2
- LAMP1 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as COSV100208562; called by muse, mutect2, varscan2
- LNX2 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as rs746655734, COSV100310622; called by muse, mutect2, varscan2
- LRPPRC | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.156); catalogued as rs764249363, COSV99580345; called by muse, mutect2, varscan2
- LRRC6 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51549056, COSV99137888; called by muse, mutect2, varscan2
- LRRIQ1 | c.468A>G p.I156M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as COSV101277707; called by muse, mutect2, varscan2
- MAML2 | c.3031C>T p.Q1011* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs993930899, COSV101594082; called by muse, mutect2, varscan2
- MBOAT1 | c.572A>G p.N191S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745554684, COSV100208633; called by muse, mutect2
- MCHR2 | c.802C>A p.H268N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99911803; called by muse, varscan2
- MECP2 | c.909C>G p.I303M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs61751439, CM041388, COSV57654475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPZL1 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV63256027; called by muse, mutect2, varscan2
- MSL3 | c.747G>A p.K249= (on ENST00000312196 / NM_078629.4; = p.K83= on NM_006800.4) | Splice Region (SNP) | VAF 13/54 reads (24%) | catalogued as rs1234204951, COSV100384722, COSV56492217; called by muse, mutect2, varscan2
- MTF1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV100888614; called by muse, mutect2, varscan2
- MUC5AC | c.745C>G p.Q249E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.1); catalogued as COSV100650569; called by muse, mutect2, varscan2
- MYO6 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889338; called by muse, mutect2, varscan2
- MYOM2 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs539873539, COSV100036637; called by muse, mutect2
- NAV3 | c.3158C>A p.P1053H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs537721481, COSV99889220; called by muse, mutect2, varscan2
- NEDD1 | c.1112A>T p.K371I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV99900911; called by muse, mutect2, varscan2
- NFAT5 | c.4192C>T p.L1398F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs1202614548, COSV100590663; ClinVar: uncertain significance; called by muse, mutect2
- OR10A2 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV56299520; called by muse, mutect2, varscan2
- OR1L6 | c.671T>G p.L224R (on ENST00000373684; = p.L188R on NM_001004453.2) | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100490857; called by muse, mutect2, varscan2
- OR4D11 | c.729C>A p.H243Q | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); catalogued as COSV100506514, COSV57585067; called by muse, mutect2, varscan2
- OR5F1 | c.459G>C p.L153F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99558534; called by muse, mutect2, varscan2
- PAX6 | c.328G>T p.G110W | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53795657, COSV99570304; called by muse, mutect2, varscan2
- PCDH12 | c.2608C>G p.P870A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV99187000; called by muse, mutect2, varscan2
- PCDHB7 | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 23/861 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99176686; called by muse, mutect2
- PCDHGA9 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.047); catalogued as rs764725441, COSV99535128; called by muse, mutect2, varscan2
- PHF3 | c.2726G>C p.G909A | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100013150; called by muse, mutect2, varscan2
- PIGW | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs757111382; called by muse, mutect2, varscan2
- PLD1 | c.2197C>G p.Q733E | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.593); catalogued as COSV60569935; called by muse, mutect2
- PLD2 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99562234; called by muse, mutect2, varscan2
- PLEKHG4 | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs749629984, COSV100430829; called by muse, mutect2, varscan2
- POLR3GL | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1553763229, COSV100996765; called by muse, mutect2, varscan2
- PPEF1 | c.614G>C p.R205P | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100583668; called by muse, mutect2, varscan2
- PRPF8 | c.6214G>C p.E2072Q | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100025408; called by muse, mutect2, varscan2
- PSD | c.2068G>T p.D690Y | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99192368; called by muse, mutect2, varscan2
- PSD | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50042711; called by muse, mutect2, varscan2
- PTPRA | c.550G>C p.G184R | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.84); catalogued as COSV99399545; called by muse, mutect2, varscan2
- PTPRB | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99716780; called by muse, mutect2, varscan2
- PTPRC | c.3493C>G p.L1165V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.163); catalogued as COSV100722426, COSV61421838; called by muse, mutect2, varscan2
- PUM2 | c.2402G>C p.G801A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100163438, COSV100163644; called by muse, mutect2
- RASGRF1 | c.1404G>A p.M468I | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs771079741, COSV101369560; called by muse, mutect2, varscan2
- RNMT | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100054559; called by muse, mutect2, varscan2
- RPS6KA2 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs753437594, COSV99690574; called by muse, mutect2, varscan2
- SALL1 | c.2293C>A p.Q765K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99173107; called by muse, mutect2, varscan2
- SEPHS1 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV59259241; called by muse, mutect2, varscan2
- SGCZ | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as COSV101168210, COSV66033703; called by muse, mutect2, varscan2
- SH3BGRL2 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100877592; called by muse, mutect2, varscan2
- SIN3A | c.2089A>T p.K697* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100845115; called by muse, mutect2, varscan2
- SLC17A4 | c.1029C>G p.I343M | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV100930546; called by muse, mutect2, varscan2
- SLC25A3 | c.332T>G p.L111R (on ENST00000228318 / NM_005888.3; = p.L110R on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as COSV99499125; called by muse, mutect2, varscan2
- SLC43A3 | c.825C>G p.F275L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100725168; called by muse, mutect2, varscan2
- SLC6A5 | c.1396-2A>G p.X466_splice | Splice Site (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100116705; called by muse, mutect2, varscan2
- SLC7A2 | c.1635G>C p.W545C (on ENST00000494857 / NM_001370338.1; = p.W584C on NM_003046.6) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs746161315, COSV99134594; called by muse, mutect2, varscan2
- SLCO4C1 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100194736, COSV60513214; called by muse, varscan2
- SMARCAL1 | c.2539C>G p.Q847E | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs746003613, COSV100619847; called by muse, mutect2, varscan2
- SNX8 | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV99770737; called by muse, mutect2, varscan2
- SOCS6 | c.1386C>G p.I462M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV101205705; called by muse, mutect2, varscan2
- SPHKAP | c.3922G>T p.E1308* | Nonsense Mutation (SNP) | VAF 37/81 reads (46%) | catalogued as COSV100763981; called by muse, mutect2, varscan2
- SRSF9 | c.654C>G p.F218L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as COSV99037890, COSV99985013; called by muse, mutect2, varscan2
- STARD13 | c.2168A>C p.Y723S (on ENST00000336934 / NM_001243476.3; = p.Y605S on NM_052851.3) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715685; called by muse, mutect2, varscan2
- STARD6 | c.491A>C p.Y164S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); catalogued as COSV100323402; called by muse, mutect2, varscan2
- SVEP1 | c.3802G>C p.E1268Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.052); catalogued as COSV100237706; called by muse, mutect2, varscan2
- SYNE1 | c.697A>T p.R233* (on ENST00000367255 / NM_182961.4; = p.R240* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99559327; called by muse, mutect2, varscan2
- SYNGAP1 | c.1514A>G p.Y505C | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99538171; called by muse, mutect2, varscan2
- SYNGR1 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53368413, COSV99335556; called by muse, mutect2, varscan2
- TDRD5 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99675922; called by muse, mutect2, varscan2
- TENT5D | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV57637208, COSV57639044; called by muse, mutect2, varscan2
- TGM4 | c.1010C>A p.P337Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.887); catalogued as COSV56094692, COSV99942234; called by muse, mutect2, varscan2
- TIA1 | c.471A>C p.K157N (on ENST00000433529 / NM_001351511.1; = p.K146N on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99248551; called by muse, mutect2, varscan2
- TMEM132B | c.1621A>C p.N541H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV100169153; called by muse, mutect2, varscan2
- TMEM132D | c.904G>T p.G302* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV101397198; called by muse, mutect2, varscan2
- TMEM270 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV100260324; called by muse, mutect2, varscan2
- TMEM270 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV100260326; called by muse, mutect2, varscan2
- TMTC2 | c.1226C>G p.T409R | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs754452313, COSV58263248; called by muse, mutect2
- TOGARAM2 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369968827; called by muse, mutect2, varscan2
- TRIML2 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.303); catalogued as COSV100455991; called by muse, mutect2, varscan2
- TRIO | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100710189; called by muse, mutect2, varscan2
- TRPM7 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.31); catalogued as COSV100539665; called by muse, mutect2
- TTC8 | c.265A>G p.T89A (on ENST00000338104 / NM_001288781.1; = p.T99A on NM_144596.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100581230; called by muse, mutect2, varscan2
- TTN | c.31237C>G p.R10413G (on ENST00000591111; = p.R9486G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | PolyPhen benign (0.045); catalogued as COSV100604322, COSV59923102; called by muse, mutect2, varscan2
- UGT2B10 | c.868-1G>A p.X290_splice | Splice Site (SNP) | VAF 16/97 reads (16%) | catalogued as rs782107811, COSV99607792; called by muse, mutect2, varscan2
- USH2A | c.9731T>G p.I3244S | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100232575; called by muse, mutect2, varscan2
- USP8 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100208907; called by muse, mutect2, varscan2
- VAT1L | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs373719090; called by muse, mutect2, varscan2
- VCAN | c.7235A>G p.K2412R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV99425327; called by muse, mutect2, varscan2
- XKR7 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1568875299, COSV101629245; called by muse, mutect2, varscan2
- ZFYVE1 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs1411060748, COSV59612903; called by muse, mutect2, varscan2
- ZNF157 | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100998476, COSV100998491; called by muse, mutect2, varscan2
- ZNF610 | c.383C>A p.T128N | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100016772; called by muse, mutect2, varscan2
- ZNF626 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV101656971; called by muse, mutect2, varscan2
- ZNF804A | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV100167277, COSV56445785; called by muse, mutect2, varscan2
- ZNF862 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370415921; called by muse, mutect2, varscan2
- ZSWIM3 | c.2011G>T p.V671L | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV99666384; called by muse, mutect2, varscan2
- BAP1 | c.1155_1156dup p.V386Efs*45 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- DMD | c.9362T>A p.L3121* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- DSE | c.2229_2230delinsG p.Q744Rfs*35 | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | called by pindel, varscan2*
- DUSP7 | c.906_908dup p.W302_S303insR | In Frame Ins (INS) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- FRMD4B | c.3069_3070del p.F1023Lfs*3 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- IGKV3D-11 | c.293T>A p.L98Q | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MRPL24 | c.117del p.R40Gfs*26 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | called by mutect2, pindel, varscan2
- MRPL35 | c.226del p.N77Ifs*11 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | called by mutect2, pindel, varscan2
- OR2S2 | c.391del p.R132Gfs*4 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- SPAG9 | c.1060G>A p.D354N (on ENST00000262013 / NM_001130528.3; = p.D340N on NM_003971.6) | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.031); called by muse, mutect2
- ACOT6 | c.105A>T p.T35= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV101141918; called by muse, mutect2, varscan2
- ACOX2 | c.1434C>T p.T478= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs373756561; called by muse, mutect2, varscan2
- ACSS3 | c.1359T>C p.T453= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99698560; called by muse, mutect2, varscan2
- ACTR3B | c.1047C>T p.L349= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs146208789; called by muse, mutect2, varscan2
- ANKLE2 | c.2136G>A p.A712= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs762852125, COSV100514044; called by muse, mutect2, varscan2
- CCDC33 | c.1044C>T p.I348= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs200133344, COSV100351190; called by muse, mutect2, varscan2
- CDK4 | c.399C>T p.A133= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV99225946; called by muse, mutect2, varscan2
- CSMD3 | c.9063C>T p.C3021= (on ENST00000297405 / NM_001363185.1; = p.C2852= on NM_052900.3) | Silent (SNP) | VAF 43/74 reads (58%) | catalogued as COSV99830641; called by muse, mutect2, varscan2
- CYP2C18 | c.471A>G p.R157= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99608429; called by muse, mutect2, varscan2
- EIF5A2 | c.69G>A p.S23= | Silent (SNP) | VAF 27/268 reads (10%) | catalogued as COSV99858619; called by muse, mutect2, varscan2
- FLNC | c.5043G>A p.T1681= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs200405579, COSV57954839, COSV57958410; called by muse, mutect2, varscan2
- GABRA6 | c.471C>G p.P157= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV50895567, COSV99194248; called by muse, mutect2, varscan2
- GCG | c.339C>T p.G113= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as COSV64961449; called by muse, mutect2, varscan2
- GLI2 | c.2385G>A p.T795= (on ENST00000361492 / NM_001374353.1; = p.T812= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV58042399; called by muse, mutect2, varscan2
- GPAT3 | c.441G>C p.L147= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as COSV100022920; called by muse, mutect2, varscan2
- GPATCH1 | c.1509C>T p.F503= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99403907; called by muse, mutect2, varscan2
- GPR149 | c.297T>A p.G99= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV101078309; called by muse, mutect2, varscan2
- HHIP | c.1074C>T p.L358= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99666988; called by muse, mutect2, varscan2
- HOXD8 | c.600A>G p.G200= | Silent (SNP) | VAF 50/115 reads (43%) | catalogued as COSV100497052; called by muse, mutect2, varscan2
- IGHG2 | c.564G>C p.V188= | Silent (SNP) | VAF 40/268 reads (15%) | called by muse, mutect2, varscan2
- KCNB1 | c.958C>T p.L320= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100870433; called by muse, mutect2, varscan2
- MCAT | c.159G>A p.A53= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs887408636, COSV99295637; called by muse, mutect2
- MCF2L2 | c.2925C>T p.G975= | Silent (SNP) | VAF 72/182 reads (40%) | catalogued as COSV100191989; called by muse, mutect2, varscan2
- MTNR1A | c.933C>G p.V311= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV100208170; called by muse, mutect2, varscan2
- MUC16 | c.16494C>A p.T5498= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV101199317; called by muse, mutect2, varscan2
- MYO5A | c.3354C>T p.S1118= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100697532; called by muse, mutect2, varscan2
- NAV3 | c.384C>A p.I128= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs1264454692, COSV99889214, COSV99897400; called by muse, mutect2, varscan2
- NPY2R | c.915C>G p.L305= | Silent (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2
- OR2M2 | c.279T>A p.S93= | Silent (SNP) | VAF 68/313 reads (22%) | catalogued as COSV100677212; called by muse, mutect2, varscan2
- OR4K5 | c.918G>A p.L306= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs1156867667, COSV100262275; called by muse, mutect2, varscan2
- PAPPA | c.2547G>A p.E849= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100073549; called by muse, mutect2, varscan2
- PCDHA8 | c.1863G>A p.P621= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as rs782819477, COSV65326697; called by muse, mutect2, varscan2
- PCDHB7 | c.2070G>T p.V690= | Silent (SNP) | VAF 24/853 reads (3%) | catalogued as COSV50756690; called by muse, mutect2
- PKD1L1 | c.4881C>T p.P1627= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99219194; called by muse, mutect2, varscan2
- PMFBP1 | c.2523G>A p.L841= (on ENST00000537465; = p.L836= on NM_031293.3) | Silent (SNP) | VAF 35/172 reads (20%) | catalogued as COSV99400615; called by muse, mutect2, varscan2
- PPP2R3A | c.2640A>G p.A880= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99386834; called by muse, mutect2, varscan2
- PPP6R3 | c.142C>T p.L48= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs758885977, COSV55737012, COSV99676100; called by muse, mutect2, varscan2
- PRAMEF4 | c.87C>T p.T29= | Silent (SNP) | VAF 55/265 reads (21%) | catalogued as rs1454659020, COSV99339678; called by muse, mutect2, varscan2
- PRKCE | c.741C>A p.I247= | Silent (SNP) | VAF 45/223 reads (20%) | catalogued as COSV100077431; called by muse, mutect2, varscan2
- REG3A | c.363G>A p.E121= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV100532632; called by muse, mutect2, varscan2
- RLIM | c.600A>T p.T200= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV100222931; called by muse, mutect2, varscan2
- ROBO2 | c.2586A>T p.I862= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100165678; called by muse, mutect2, varscan2
- SCN2A | c.4059C>T p.I1353= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99330976; called by muse, mutect2, varscan2
- SDF4 | c.420C>T p.R140= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs558543239, COSV99767530; called by muse, mutect2, varscan2
- SLC38A5 | c.387A>C p.T129= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100476439; called by muse, mutect2
- SYNE1 | c.20355G>A p.K6785= (on ENST00000367255 / NM_182961.4; = p.K6714= on NM_033071.3) | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV99559320; called by muse, mutect2, varscan2
- TAF11 | c.207T>C p.V69= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100781026; called by muse, mutect2, varscan2
- TELO2 | c.189C>T p.L63= | Silent (SNP) | VAF 23/152 reads (15%) | catalogued as rs1327420921, COSV51979132, COSV99248182; called by muse, mutect2, varscan2
- TLR4 | c.1863G>A p.L621= (on ENST00000355622 / NM_138554.5; = p.L581= on NM_003266.4) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100842722; called by muse, mutect2, varscan2
- TMEM74B | c.561C>T p.G187= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs780392857, COSV101121966; called by muse, mutect2, varscan2
- TRAT1 | c.375G>A p.R125= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs143422005, COSV55469414; called by muse, mutect2, varscan2
- TRPM1 | c.813G>A p.E271= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs749773584, COSV99855705; called by muse, mutect2, varscan2
- TTN | c.84318C>G p.T28106= (on ENST00000591111; = p.T20682= on NM_003319.4) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100604319; called by muse, mutect2, varscan2
- TTN | c.20445T>C p.T6815= (on ENST00000591111; = p.T5888= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV100604326; called by muse, mutect2, varscan2
- UBE2S | c.609C>T p.R203= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs1320986420, COSV99198768; called by muse, mutect2, varscan2
- ZNF106 | c.5292C>G p.V1764= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs150699545; called by muse, mutect2, varscan2
- ZNF391 | c.526C>A p.R176= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV55124355, COSV99772531; called by muse, mutect2, varscan2
- ZNF454 | c.102C>T p.A34= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV100194792; called by muse, mutect2, varscan2
- ZNF536 | c.1773G>A p.Q591= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV100834994, COSV62823632; called by muse, mutect2, varscan2
- ZNF561 | c.405A>C p.T135= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100254431; called by muse, mutect2, varscan2
- BCAS3 | c.2075-5022C>T | Intron (SNP) | VAF 30/117 reads (26%) | catalogued as rs1482435269, COSV101175675; called by muse, mutect2, varscan2
- CLCN5 | c.17-39091A>T | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as COSV101067051; called by muse, mutect2, varscan2
- DCHS2 | n.8313G>C | RNA (SNP) | VAF 14/57 reads (25%) | catalogued as COSV61768951; called by muse, mutect2, varscan2
- MAP7D2 | c.595+1990C>A | Intron (SNP) | VAF 3/11 reads (27%) | catalogued as COSV101107289; called by muse, mutect2
- MFRP | chr11:119344357 A>T | 5'Flank (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100793388; called by muse, mutect2, varscan2
- MIR539 | n.7G>C | RNA (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.839-858C>T | Intron (SNP) | VAF 32/197 reads (16%) | catalogued as COSV100514296; called by muse, mutect2, varscan2
- ZSCAN32 | c.839-859G>C | Intron (SNP) | VAF 32/196 reads (16%) | catalogued as COSV100514297; called by muse, mutect2, varscan2
